Gene-level copy-number profile of tumor specimen TCGA-HG-A2PA-01A from TCGA case TCGA-HG-A2PA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 38.4 years (14,025 days).
Specimen TCGA-HG-A2PA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.6789b31f-37e7-4b61-9467-4599fbf6abdf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HG-A2PA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/65597f89-ef18-4eae-ace9-19a7d768d9fc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,285; copy number 3: 336; copy number 4: 46,287; copy number 6: 4,834; copy number 7: 689; copy number 11: 258; copy number 14: 20; copy number 15: 57; copy number 21: 12; copy number 22: 37; copy number 25: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HG-A2PA-01A-11D-A20T-01): tumor purity 0.5, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 385 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:30,516,266–32,407,763, 187 genes, copy number 11 (broad region; genes not listed).
- chr6:42,744,498–45,377,953, 94 genes, copy number 15–22 (within-gene range 2–22) (broad region; genes not listed).
- chr6:55,327,469–55,940,624, 5 genes, copy number 11–25 (within-gene range 6–25): GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36.
- chr20:31,356,870–33,913,336, 99 genes, copy number 11–21 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
